TARGET case TARGET-30-PATJZC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Heart, mediastinum, and pleura. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/00acddd3-4c36-52f7-b051-52b263d8e1e4

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Dead; Days to death: 282 days.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C38.2; Tissue or organ of origin: Posterior mediastinum; Classification of tumor: primary; Age at diagnosis: 0.9 years (325 days); Year of diagnosis: 2010; Days to last follow up: 282 days; Cog neuroblastoma risk group: Intermediate Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 70.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0531.

Follow-up (2 entries)
- Days to follow up: 207 days; Days to first event: 207 days; First event: Event.
- Days to follow up: 282 days; Year of follow up: 2011.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PATJZC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PATJZC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 282
- Protocol: ANBL00B1, ANBL0531
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Favorable
- MKI: Low
